Gene-level copy-number profile of tumor specimen TCGA-A2-A0T4-01A from TCGA case TCGA-A2-A0T4, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.6 years (22,849 days).
Specimen TCGA-A2-A0T4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.504fc7b4-3097-420e-b9e0-8981e934c2b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0T4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/21b30b6f-ad91-4dc8-b70a-aa198d8f5ee7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,119; copy number 2: 45,440; copy number 3: 2,931; copy number 4: 5; copy number 5: 2; copy number 6: 50; copy number 7: 51; copy number 8: 4; copy number 9: 133; copy number 10: 34; copy number 13: 45; copy number 14: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0T4-01A-31D-A087-01): tumor purity 0.49, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 324 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:50,818,723–50,913,256, 4 genes, copy number 8: TFAP2B, RPS17P5, AL049693.1, FTH1P5.
- chr6:51,975,673–54,945,099, 77 genes, copy number 6–14 (broad region; genes not listed).
- chr6:56,331,788–60,546,660, 32 genes, copy number 6 (within-gene range 2–6): AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1, AC244258.1.
- chr11:65,883,740–67,258,082, 77 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr11:68,612,899–69,926,813, 36 genes, copy number 6–10: AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2.
- chr11:72,072,228–73,142,318, 46 genes, copy number 7 (within-gene range 1–7): MIR3165, AP000812.4, LRTOMT, LAMTOR1, AP000812.3, ANAPC15, FOLR3, RPEP6, FOLR1P1, AP000812.1, AP000812.2, FOLR1, FOLR2, INPPL1, PHOX2A, AP000593.2, AP000593.4, AP000593.1, CLPB, AP000593.3, AP002892.2, AP002892.1, AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1.
- chr11:76,381,303–76,591,211, 5 genes, copy number 7: GVQW3, Y_RNA, AP002360.1, EMSY, AP001189.2.
- chr11:76,782,251–76,798,153, 1 gene, copy number 5 (within-gene range 3–5): TSKU.
- chr11:76,800,364–78,574,874, 46 genes, copy number 5–13 (within-gene range 1–13): AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1.

Autosomal genes at a single copy (total copy number 1): 11,119. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
